Gene-level copy-number profile of tumor specimen TCGA-GC-A6I1-01A from TCGA case TCGA-GC-A6I1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-GC-A6I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.85058c6c-f5f6-4536-9e7d-e6728bee1242.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GC-A6I1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f91e0690-84d9-4a3e-868e-0573d407fa81

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 5,098; copy number 2: 45,773; copy number 3: 5,029; copy number 4: 3,216; copy number 5: 39; copy number 6: 519; copy number 7: 37; copy number 9: 15; copy number 12: 82.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GC-A6I1-01A-12D-A31K-01): tumor purity 0.31, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr5:166,905,222–168,264,157, 9 genes (within-gene range 0–1): LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 692 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:216,503,246–240,475,187, 503 genes, copy number 6–9 (broad region; genes not listed).
- chr3:74,262,568–74,521,140, 1 gene, copy number 6 (within-gene range 2–6): CNTN3.
- chr11:66,848,417–71,252,577, 149 genes, copy number 6–12 (within-gene range 2–12) (broad region; genes not listed).
- chr18:23,506,184–24,708,542, 33 genes, copy number 5 (within-gene range 2–5): NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57.
- chr20:55,074,644–55,781,231, 6 genes, copy number 5: RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1.

Autosomal genes at a single copy (total copy number 1): 3,233. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
